Somatic mutation profile of tumor specimen TARGET-20-PATHVG-04A (aliquot TARGET-20-PATHVG-04A-01D) from TARGET case TARGET-20-PATHVG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.8 years (275 days).
Specimen TARGET-20-PATHVG-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 871eeb74-0180-4409-b394-091278e02b8d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATHVG-14A (Bone Marrow Normal), aliquot TARGET-20-PATHVG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c85bf5c-faf6-4b76-8ba3-eee6c4343165

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1358A>G p.H453R | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as CM042136, COSV60066774, COSV60069640; called by muse, mutect2, varscan2
